Gene-level copy-number profile of tumor specimen TCGA-DX-A6BK-01A from TCGA case TCGA-DX-A6BK, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 85.3 years (31,159 days).
Specimen TCGA-DX-A6BK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.b6ad3e48-5d27-4b73-9041-dd5ef8ac233b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6BK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f553fcb1-5cf4-4484-a321-ad5fbed3fc5f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 60; copy number 1: 141; copy number 2: 6,947; copy number 3: 13,391; copy number 4: 27,844; copy number 5: 8,584; copy number 6: 1,744; copy number 7: 585; copy number 8: 187; copy number 9: 107; copy number 10: 25; copy number 11: 32; copy number 13: 109; copy number 14: 7; copy number 16: 11; copy number 69: 27; copy number 79: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6BK-01A-11D-A306-01): tumor purity 0.33, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:13,105,706–13,279,692, 1 gene (within-gene range 0–9): MPDZ.
- chr9:21,160,235–23,438,700, 55 genes (within-gene range 0–2): Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1.
- chr9:24,905,469–25,678,440, 4 genes: RMRPP5, RN7SKP120, AL353730.1, TUSC1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 329 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:84,638,405–84,893,379, 3 genes, copy number 10: LINC00971, AC117482.1, LINC02025.
- chr3:86,876,388–87,793,629, 11 genes, copy number 79: VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P.
- chr5:8,717,684–9,546,075, 9 genes, copy number 11 (within-gene range 8–11): AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636.
- chr9:6,704,270–7,961,224, 15 genes, copy number 10–14 (within-gene range 8–14): LINC02851, AL354707.1, KDM4C, PRELID3BP11, SNRPEP2, ACTG1P14, AL513412.1, AL161443.1, AL157703.1, RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1.
- chr9:8,700,595–9,091,245, 6 genes, copy number 10: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3.
- chr9:13,274,510–13,945,610, 6 genes, copy number 9: AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583.
- chr9:14,586,766–16,870,843, 32 genes, copy number 9 (within-gene range 5–9): AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1.
- chr9:27,937,617–29,826,711, 12 genes, copy number 9: AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1.
- chr12:4,012,902–6,124,770, 42 genes, copy number 10–16 (within-gene range 3–16): AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1, GALNT8, AC005833.2, KCNA6, AC006063.1, AC006063.3, AC006063.4, AC005906.2, KCNA1, AC006063.2, AC005906.1, KCNA5, AC005906.3, LINC02443, AC006206.2, AC006206.1, AC007848.2, AC007848.1, NTF3, ANO2, AC137627.1, VWF.
- chr13:89,833,157–89,837,237, 2 genes, copy number 9: RPL7L1P1, AL355821.1.
- chr13:110,148,963–110,307,157, 2 genes, copy number 9 (within-gene range 5–9): COL4A1, AL161773.1.
- chr17:66,787,072–68,422,731, 53 genes, copy number 9: MIR634, CACNG5, RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1, HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6.
- chr18:46,173,553–47,251,660, 27 genes, copy number 69: C18orf25, RNF165, AC015959.1, AC018931.1, LOXHD1, ST8SIA5, AC090311.1, AC090241.2, AC090241.3, PIAS2, AC090241.1, AC090373.1, KATNAL2, ELOA3D, ELOA3C, ELOA3B, ELOA3, ELOA2, AC012254.5, AC012254.1, AC012254.3, HDHD2, AC012254.2, AC012254.4, IER3IP1, SKOR2, RNU6-1131P.
- chr19:38,730,187–40,591,399, 109 genes, copy number 13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 141. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
